Somatic mutation profile of tumor specimen f69deaeb-6b6f-4c61-8900-fd0f26 (aliquot f69deaeb-6b6f-4c61-8900-fd0f26_D6_2) from CPTAC case 09CO022, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIB.
Specimen f69deaeb-6b6f-4c61-8900-fd0f26: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ef08a2c-8c2e-4236-b137-b3beab7db7b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 60805d52-8ca1-46d4-8101-0ad055 (Blood Derived Normal), aliquot 60805d52-8ca1-46d4-8101-0ad055_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc376316-aacc-4462-bc20-3b622b63ec0b

The open-access MAF lists 172 somatic variants for this specimen: 119 protein-altering or splice-affecting, 34 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 34, Nonsense Mutation 6, Frame Shift Del 5, Intron 5, 5'UTR 4, RNA 4, Frame Shift Ins 3, 3'UTR 2, 5'Flank 2, 3'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 102/279 reads (37%) | catalogued as rs137852217, CM090019, COSV57654223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 74/189 reads (39%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 118/284 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPC1 | c.3160G>A p.A1054T | Missense Mutation (SNP) | VAF 134/294 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs80358258, CM012441; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 205/366 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AP2A2 | c.170dup p.Y58Vfs*14 | Frame Shift Ins (INS) | VAF 34/110 reads (31%) | catalogued as rs753029866; called by mutect2, varscan2
- ARSI | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 261/757 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs772194968, COSV60816873; called by muse, mutect2, varscan2
- CCIN | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 117/354 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs762753747, COSV58724905; called by muse, mutect2, varscan2
- CDON | c.3293C>T p.T1098M | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1260225651; called by muse, mutect2, varscan2
- CLCN7 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 101/310 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs923808258; called by muse, mutect2, varscan2
- CMYA5 | c.8627C>T p.A2876V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150027467; called by muse, mutect2, varscan2
- CNOT1 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57784161; called by muse, mutect2, varscan2
- COL5A3 | c.3097G>A p.V1033I | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as rs370189164; called by muse, mutect2
- DKKL1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as rs998748923, COSV99678559; called by muse, mutect2, varscan2
- DOCK7 | c.3890C>T p.S1297L (on ENST00000635253 / NM_001367561.1; = p.S1266L on NM_033407.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as rs755928702, COSV52004224; called by muse, mutect2, varscan2
- ELMO1 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs1447676557, COSV60297074; called by muse, mutect2, varscan2
- FADS1 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as rs1188442891; called by muse, mutect2, varscan2
- GDF1 | c.-915C>T | Splice Region (SNP) | VAF 37/105 reads (35%) | catalogued as rs779362030; called by muse, mutect2, varscan2
- GEMIN7 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 104/298 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs140936548; called by muse, mutect2, varscan2
- GRIK3 | c.1937C>T p.T646M | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277838021, COSV66135068; called by muse, mutect2, varscan2
- H1-8 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770115798, COSV60974484; called by muse, mutect2, varscan2
- HELZ | c.2822C>T p.A941V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs752069712; called by muse, mutect2, varscan2
- HMGA2 | c.256_258del p.Q86del | In Frame Del (DEL) | VAF 26/87 reads (30%) | catalogued as rs754798604; called by pindel, varscan2
- HTR3D | c.1282G>A p.A428T (on ENST00000382489 / NM_001163646.2; = p.A253T on NM_182537.3) | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs377613674; called by muse, mutect2, varscan2
- IGFALS | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 241/713 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs200564045, COSV51905097, COSV99236303; called by muse, mutect2, varscan2
- IRF4 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706083; called by muse, mutect2, varscan2
- ITGB7 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 208/570 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs747774269; called by muse, varscan2
- JAKMIP3 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as rs762758891, COSV53826329; called by muse, mutect2, varscan2
- KCNA4 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 102/298 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs1473161691, COSV60252311; called by mutect2, varscan2
- KCTD11 | c.317G>A p.R106Q (on ENST00000333751 / NM_001363642.1; = p.R67Q on NM_001002914.2) | Missense Mutation (SNP) | VAF 57/308 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs763611334; called by muse, mutect2, varscan2
- KLHL4 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.224); catalogued as rs1296214364; called by muse, mutect2, varscan2
- LRFN1 | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 166/465 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); catalogued as COSV50439707; called by muse, mutect2, varscan2
- LRFN5 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1476091978; called by muse, mutect2, varscan2
- LRP5 | c.2872C>T p.R958W | Missense Mutation (SNP) | VAF 140/448 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754174678; called by muse, mutect2, varscan2
- LRRC43 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); catalogued as rs942534186, COSV60289174; called by muse, mutect2
- MAGEA6 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 79/296 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.159); catalogued as COSV100262713; called by muse, mutect2, varscan2
- MAGEC3 | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 26/548 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV68923869; called by muse, mutect2
- MON2 | c.3373A>C p.I1125L | Missense Mutation (SNP) | VAF 108/292 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs1283874187; called by muse, varscan2
- MOV10L1 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 108/348 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs751559185; called by muse, mutect2
- MTPAP | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs759258615; called by muse, mutect2, varscan2
- NADSYN1 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 96/295 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs775486610; called by muse, mutect2, varscan2
- NBEAL2 | c.6094C>T p.R2032W | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746738199; called by muse, mutect2, varscan2
- NCOR2 | c.4171C>T p.R1391W | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759677157, COSV100657887; called by muse, mutect2, varscan2
- NLGN4X | c.2309A>G p.D770G | Missense Mutation (SNP) | VAF 156/508 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as rs747933546; called by muse, mutect2, varscan2
- NRK | c.3191G>A p.G1064E | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs763158879; called by muse, mutect2, varscan2
- OR2K2 | c.237C>G p.I79M (on ENST00000374428; = p.I50M on NM_205859.2) | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV100235321; called by muse, mutect2
- PALM2AKAP2 | c.980G>A p.R327H (on ENST00000259318 / NM_001136562.3; = p.R558H on NM_007203.5) | Missense Mutation (SNP) | VAF 133/406 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs755205853, COSV99395545; called by muse, mutect2, varscan2
- PCDH15 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.547); catalogued as rs1402798500, COSV57307241; called by muse, mutect2, varscan2
- PCDH17 | c.2879C>A p.A960E | Missense Mutation (SNP) | VAF 95/397 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.111); catalogued as COSV64976957; called by muse, mutect2, varscan2
- PIK3CD | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs201282174; called by muse, mutect2, varscan2
- RAD21 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52060821; called by muse, mutect2, varscan2
- RNASEH2B | c.370A>G p.N124D | Missense Mutation (SNP) | VAF 180/656 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs757415855; called by muse, mutect2, varscan2
- RP1 | c.2831G>T p.R944I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.452); catalogued as rs1195151040; called by muse, mutect2, varscan2
- RYR2 | c.5821C>T p.R1941C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as rs754811291; called by muse, mutect2, varscan2
- SH2D5 | c.595C>T p.R199W (on ENST00000444387 / NM_001103161.2; = p.R115W on NM_001103160.2) | Missense Mutation (SNP) | VAF 108/305 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs774369562, COSV66707621; called by muse, mutect2, varscan2
- SRCAP | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 63/180 reads (35%) | catalogued as COSV104390888; called by mutect2, varscan2
- ST3GAL1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 97/207 reads (47%) | PolyPhen probably damaging (0.948); catalogued as rs1233734180; called by muse, mutect2, varscan2
- SYCE1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.987); catalogued as rs868710053; called by muse, mutect2, varscan2
- TAF7 | c.928del p.E310Kfs*34 | Frame Shift Del (DEL) | VAF 66/212 reads (31%) | catalogued as COSV57664818; called by mutect2, pindel, varscan2
- TGFBRAP1 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1260193168, COSV99304965; called by muse, mutect2, varscan2
- TIMM50 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs554175685; called by muse, varscan2
- TMEM151A | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 87/304 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs866365915, COSV100517091; called by muse, mutect2, varscan2
- TRBC2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 166/614 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.171); catalogued as rs544245790; called by muse, varscan2
- TRPC5 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs374332395; called by mutect2, varscan2
- UGT3A1 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 124/361 reads (34%) | catalogued as rs61734803, COSV57099785; called by mutect2, varscan2
- VAV2 | c.1846G>A p.V616M (on ENST00000371850 / NM_001134398.2; = p.V606M on NM_003371.4) | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); catalogued as rs747112648, COSV100896229; called by muse, mutect2, varscan2
- XAB2 | c.2096C>T p.T699M | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs770164799; called by muse, mutect2, varscan2
- ZNF575 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs754164879; called by muse, mutect2, varscan2
- ZSCAN5A | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 114/339 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs141778812; called by muse, mutect2, varscan2
- AC024598.1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAD1 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS12 | c.2475G>A p.M825I | Missense Mutation (SNP) | VAF 108/339 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- APC | c.1438dup p.Q480Pfs*5 | Frame Shift Ins (INS) | VAF 48/168 reads (29%) | called by mutect2, varscan2
- ATG16L2 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- BCL9 | c.1782del p.D594Efs*65 | Frame Shift Del (DEL) | VAF 89/331 reads (27%) | called by mutect2, pindel, varscan2
- C1QTNF9 | c.763A>C p.I255L | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCDC110 | c.2362A>C p.T788P | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.062); called by muse, mutect2
- DNASE1L2 | c.716C>G p.T239R | Missense Mutation (SNP) | VAF 34/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DTNBP1 | c.150A>T p.E50D | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPB41L4A | c.1362G>T p.Q454H | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- FAM186A | c.6165A>T p.R2055S | Missense Mutation (SNP) | VAF 110/283 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGD2 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 115/330 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FRMPD4 | c.2647G>T p.E883* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- GBP5 | c.727A>C p.K243Q | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- GLRA2 | c.1028G>A p.R343K | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.92); called by muse, varscan2
- GNL2 | c.2153_2154del p.E718Gfs*? | Frame Shift Del (DEL) | VAF 25/93 reads (27%) | called by pindel, varscan2
- GRIN2A | c.3896C>G p.P1299R | Missense Mutation (SNP) | VAF 206/634 reads (32%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- HERC6 | c.1548G>T p.L516F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.768); called by mutect2, varscan2
- HIBADH | c.343G>T p.G115* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- HOXA10 | c.932A>C p.K311T | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- HTR1A | c.1058C>A p.T353N | Missense Mutation (SNP) | VAF 228/708 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- JRK | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1210 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- KIAA1755 | c.347C>A p.S116Y | Missense Mutation (SNP) | VAF 107/643 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MAN2B1 | c.2690C>G p.P897R | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MSH4 | c.905G>C p.C302S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTMR8 | c.310+1G>A p.X104_splice | Splice Site (SNP) | VAF 41/136 reads (30%) | called by muse, mutect2, varscan2
- NECTIN2 | c.550A>T p.I184F | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- NKX3-1 | c.295T>A p.L99M | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- OVCH1 | c.1896C>A p.D632E | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.155); called by muse, mutect2
- POLA1 | c.4031G>A p.G1344D | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- PTPRZ1 | c.3214C>T p.P1072S | Missense Mutation (SNP) | VAF 106/333 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- REST | c.2638del p.Q880Kfs*18 | Frame Shift Del (DEL) | VAF 29/111 reads (26%) | called by mutect2, pindel, varscan2
- RTN4 | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- RXRG | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 25/274 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SH2D3C | c.649A>T p.S217C (on ENST00000314830 / NM_170600.3; = p.S60C on NM_005489.4) | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SIGLEC8 | c.1439C>T p.T480I | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLBP | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SLC27A5 | c.2023C>A p.L675M | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- SYCP2L | c.2084T>A p.V695D | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TAF5 | c.2023_2027del p.L675Ifs*36 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- TCF12 | c.182dup p.T62Nfs*10 | Frame Shift Ins (INS) | VAF 37/124 reads (30%) | called by mutect2, pindel, varscan2
- TRIM45 | c.1657T>C p.C553R | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTI1 | c.1981G>A p.G661R | Missense Mutation (SNP) | VAF 72/487 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XRCC2 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ZNF132 | c.1865C>T p.T622I | Missense Mutation (SNP) | VAF 100/265 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF148 | c.605G>C p.S202T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- ZNF30 | c.1292A>T p.K431M | Missense Mutation (SNP) | VAF 93/428 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- ZNF429 | c.458T>G p.V153G | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- AKAP14 | c.312G>A p.R104= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as COSV100538298; called by muse, mutect2, varscan2
- CMYA5 | c.5598A>G p.S1866= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV101483693; called by muse, mutect2, varscan2
- ECE1 | c.2001G>A p.E667= | Silent (SNP) | VAF 92/319 reads (29%) | catalogued as rs752567180; called by muse, mutect2, varscan2
- FAM47A | c.1095G>A p.A365= | Silent (SNP) | VAF 18/202 reads (9%) | catalogued as rs1375077987, COSV60498823; called by muse, mutect2
- FAP | c.2091C>T p.I697= | Silent (SNP) | VAF 71/228 reads (31%) | called by muse, mutect2, varscan2
- FPR3 | c.729C>T p.F243= | Silent (SNP) | VAF 68/225 reads (30%) | catalogued as rs760137716, COSV59329100; called by muse, mutect2, varscan2
- GPR158 | c.1833C>T p.R611= | Silent (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- GRM7 | c.1725A>G p.G575= | Silent (SNP) | VAF 91/261 reads (35%) | called by muse, mutect2, varscan2
- KIF1A | c.2781C>T p.P927= | Silent (SNP) | VAF 54/184 reads (29%) | catalogued as rs188912218; called by muse, mutect2, varscan2
- KLKB1 | c.1734A>C p.S578= | Silent (SNP) | VAF 38/318 reads (12%) | called by muse, mutect2, varscan2
- LARP4 | c.1635T>C p.S545= | Silent (SNP) | VAF 33/93 reads (35%) | called by muse, mutect2, varscan2
- MAP2 | c.4830T>G p.S1610= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as COSV52284688, COSV52309260, COSV99561686; called by muse, mutect2, varscan2
- MED12L | c.6075C>A p.G2025= | Silent (SNP) | VAF 89/230 reads (39%) | catalogued as COSV99853162; called by muse, varscan2
- MUC4 | c.13173T>C p.P4391= (on ENST00000463781 / NM_018406.7; = p.P155= on NM_004532.6) | Silent (SNP) | VAF 55/149 reads (37%) | called by muse, mutect2, varscan2
- NT5C1A | c.936G>A p.A312= | Silent (SNP) | VAF 84/242 reads (35%) | catalogued as rs142862392; called by muse, mutect2, varscan2
- OR4C6 | c.780G>T p.V260= | Silent (SNP) | VAF 109/357 reads (31%) | called by muse, mutect2, varscan2
- OTUD7A | c.1971C>T p.H657= (on ENST00000307050 / NM_001382637.1; = p.H650= on NM_130901.3) | Silent (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- PCDHB1 | c.1263C>T p.T421= | Silent (SNP) | VAF 48/402 reads (12%) | called by muse, mutect2, varscan2
- PIEZO1 | c.3276G>T p.R1092= | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- PLXNB2 | c.2664C>T p.V888= | Silent (SNP) | VAF 159/443 reads (36%) | called by muse, varscan2
- PLXND1 | c.1824C>T p.S608= | Silent (SNP) | VAF 159/444 reads (36%) | catalogued as rs367808121; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRAMEF20 | c.1017G>A p.P339= | Silent (SNP) | VAF 152/486 reads (31%) | catalogued as rs948202258; called by muse, mutect2, varscan2
- PSD | c.2175C>T p.A725= | Silent (SNP) | VAF 26/278 reads (9%) | catalogued as rs746913329; called by muse, mutect2
- PTRHD1 | c.225G>A p.L75= | Silent (SNP) | VAF 56/156 reads (36%) | catalogued as rs750588542; called by muse, mutect2, varscan2
- RAB7A | c.387C>T p.L129= | Silent (SNP) | VAF 52/386 reads (13%) | catalogued as rs767284504; called by mutect2, varscan2
- RYR2 | c.3180C>T p.Y1060= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs398123540, COSV63721277; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- SCART1 | c.2892C>T p.I964= | Silent (SNP) | VAF 47/156 reads (30%) | called by muse, mutect2, varscan2
- SLC5A7 | c.885A>G p.G295= | Silent (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- SLC7A14 | c.1068G>A p.P356= | Silent (SNP) | VAF 90/254 reads (35%) | catalogued as rs758020483, COSV51577816, COSV99200710; called by muse, mutect2, varscan2
- SOX2 | c.717C>G p.S239= | Silent (SNP) | VAF 50/566 reads (9%) | called by muse, mutect2
- STARD7 | c.285G>A p.L95= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs1334088024; called by muse, mutect2, varscan2
- TCHP | c.6G>T p.A2= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV57166426; called by muse, mutect2, varscan2
- TSR1 | c.1023T>C p.L341= | Silent (SNP) | VAF 63/106 reads (59%) | called by muse, mutect2, varscan2
- USP17L8 | c.129C>A p.L43= | Silent (SNP) | VAF 71/113 reads (63%) | called by muse, mutect2, varscan2
- ASPM | c.-42G>C | 5'UTR (SNP) | VAF 42/156 reads (27%) | called by muse, mutect2, varscan2
- BCAS3 | c.2075-5041G>A | Intron (SNP) | VAF 16/57 reads (28%) | catalogued as rs778296156, COSV101174830; called by muse, mutect2, varscan2
- C19orf12 | chr19:29699291 C>T | 3'Flank (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- CA9 | chr9:35669594 G>T | 5'Flank (SNP) | VAF 36/132 reads (27%) | called by mutect2, varscan2
- EFHC1 | c.*2351C>T | 3'UTR (SNP) | VAF 128/400 reads (32%) | called by muse, mutect2, varscan2
- FAM183BP | n.517C>T | RNA (SNP) | VAF 57/216 reads (26%) | catalogued as rs1160483470; called by muse, mutect2, varscan2
- HSP90AB3P | n.1879G>T | RNA (SNP) | VAF 178/575 reads (31%) | called by muse, mutect2, varscan2
- HYPK | c.-18C>G | 5'UTR (SNP) | VAF 45/142 reads (32%) | called by muse, mutect2, varscan2
- LINC00602 | n.86G>T | RNA (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- LRCH4 | c.1854+84G>A | Intron (SNP) | VAF 102/262 reads (39%) | catalogued as rs761780984, COSV99776119; called by muse, mutect2, varscan2
- NAMPTP1 | n.1084G>T | RNA (SNP) | VAF 143/404 reads (35%) | called by muse, mutect2, varscan2
- NBEAL2 | c.*203C>T | 3'UTR (SNP) | VAF 16/43 reads (37%) | catalogued as rs932810599; called by muse, mutect2, varscan2
- OR52A4P | chr11:5121083 G>T | 3'Flank (SNP) | VAF 24/391 reads (6%) | called by muse, mutect2
- RFX3 | c.474+6153T>C | Intron (SNP) | VAF 4/50 reads (8%) | catalogued as rs1420041718; called by muse, mutect2
- RNU6-389P | chr7:55685332 C>G | 5'Flank (SNP) | VAF 15/182 reads (8%) | called by muse, mutect2
- SECISBP2 | c.-19_-1del | 5'UTR (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- SRL | c.62-2751A>G | Intron (SNP) | VAF 11/280 reads (4%) | called by muse, mutect2
- TBX5 | c.-25G>A | 5'UTR (SNP) | VAF 27/173 reads (16%) | catalogued as rs748222016; called by muse, mutect2, varscan2
- YAF2 | c.152+1654G>T | Intron (SNP) | VAF 28/334 reads (8%) | called by muse, mutect2
